Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2J8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2J8-06A (Metastatic).

DIAGNOSIS

100-0-3

Melanoma, NOS 8720/3

Site lymph node, inguinal 077.4
for 7/24/11

Patient ID - Sample ID

- (A) LEFT INGUINAL LYMPH NODES:
METASTATIC MELANOMA IN SOFT TISSUE, THREE NODULES.
LARGEST TUMOR FOCUS 25.0 MM.
Completely replaced lymph nodes are likely.

GROSS DESCRIPTION

- (A) LEFT INGUINAL LYMPH NODE – Specimen is received fresh for TIL protocol. Received are three nodules ranging from 1.0 up to 2.5 cm in greatest dimension. Cut surface of the nodules is dark to light gray focally bright orange. One-half of the largest nodule is submitted for TIL study. Section of the largest nodule is given to the melanoma bank. The rest of the nodule is submitted for routine histology.

SECTION CODE: A1, A2, the rest of the largest nodule; A3, one sectioned nodule; A4, one sectioned nodule.

CLINICAL HISTORY

Melanoma

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

1. These tests have not been

Entire report and diagnosis completed by:

--END OF REPORT-----

Source: NCI Genomic Data Commons file d3b715b9-8b0f-48b6-9786-832a6368ea7c (TCGA-D3-A2J8.3D702708-2EC9-4FB6-A091-2958A7656A42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).